Somatic mutation profile of tumor specimen TARGET-40-NAAIBW-01A (aliquot TARGET-40-NAAIBW-01A-01D) from TARGET case TARGET-40-NAAIBW, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.3 years (3,031 days).
Specimen TARGET-40-NAAIBW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ee63b1e-2eae-42a6-9ad9-e21c3578dbc4.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAIBW-10B (Blood Derived Normal), aliquot TARGET-40-NAAIBW-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25ce9990-381f-4d12-8ff8-0ca033bb8043

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH10 | c.8062_8064del p.K2688del (on ENST00000409039; = p.K2627del on NM_207437.3) | In Frame Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- DNHD1 | c.5471C>T p.P1824L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1 | c.7968C>G p.H2656Q | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- PLEKHA7 | c.3208A>G p.K1070E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- RBL1 | c.1188G>C p.R396= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs1436725963; called by muse, mutect2, varscan2
